Somatic mutation profile of tumor specimen TCGA-DA-A1I7-06A (aliquot TCGA-DA-A1I7-06A-22D-A197-08) from TCGA case TCGA-DA-A1I7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.8 years (23,685 days).
Specimen TCGA-DA-A1I7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45084843-461d-4c91-b5fc-72d95118de10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I7-10A (Blood Derived Normal), aliquot TCGA-DA-A1I7-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c53a705b-8d9a-4b27-8f75-e3e513e1b9f5

The open-access MAF lists 511 somatic variants for this specimen: 329 protein-altering or splice-affecting, 170 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 170, Nonsense Mutation 19, Intron 6, RNA 3, Frame Shift Del 3, 5'Flank 2, Translation Start Site 2, In Frame Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KCNH2 | c.1193G>A p.W398* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as rs794728366, CM097339, COSV51139889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LDLR | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs776421777, CM127580, CM960928, COSV52941901; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- ABCA12 | c.719A>T p.K240M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55948937, COSV55964636; called by mutect2, varscan2
- ABCA8 | c.4487_4488del p.F1496Sfs*16 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | catalogued as COSV52200286; called by pindel, varscan2
- ACAN | c.4883G>A p.G1628E | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV61363243; called by muse, mutect2, varscan2
- ACSL5 | c.1240C>T p.R414C (on ENST00000354273; = p.R470C on NM_016234.3) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs767315343, COSV100634493, COSV61128829; called by mutect2, varscan2
- ADAMTS15 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54507229; called by muse, varscan2
- ADAMTS18 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1249046298, COSV51398246; called by muse, mutect2, varscan2
- ADGRF5 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51933841, COSV51936112, COSV99345013; called by muse, mutect2, varscan2
- ADH7 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV52921821; called by muse, mutect2, varscan2
- AGO1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV64595664; called by muse, mutect2, varscan2
- AHCTF1 | c.1186C>T p.R396* (on ENST00000366508; = p.R370* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 50/196 reads (26%) | catalogued as COSV58248386; called by mutect2, varscan2
- ALDH3A1 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV99855789; called by mutect2, varscan2
- ANGPTL5 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1238338516, COSV100527702; called by mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANKEF1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as rs1173259468, COSV65692606; called by muse, mutect2, varscan2
- ANKRD50 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as COSV72385743, COSV72385826; called by muse, mutect2, varscan2
- ANKS1B | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV61359074; called by muse, mutect2, varscan2
- ANPEP | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV55589277; called by muse, mutect2, varscan2
- APCS | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1212964116, COSV54817436, COSV54818546; called by muse, mutect2, varscan2
- APLP1 | c.1615G>A p.E539K (on ENST00000221891 / NM_001024807.3; = p.E538K on NM_005166.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV55704384; called by muse, mutect2
- APRT | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM931124, COSV51938482; called by muse, mutect2, varscan2
- ARHGAP17 | c.2557C>T p.P853S (on ENST00000289968 / NM_001006634.3; = p.P775S on NM_018054.6) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.013); catalogued as COSV51509100; called by muse, varscan2
- ARHGAP32 | c.4813C>T p.P1605S (on ENST00000310343 / NM_001378025.1; = p.P1256S on NM_014715.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1436489179, COSV59850589, COSV59857656; called by muse, mutect2, varscan2
- ARHGAP44 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52396161; called by muse, mutect2, varscan2
- ARHGEF11 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1415918437, COSV59355594; called by muse, varscan2
- ARMC2 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64551800; called by muse, varscan2
- ARMC3 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs78062147; called by mutect2, varscan2
- ASAH2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV61483935; called by muse, mutect2, varscan2
- ATMIN | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55146599; called by muse, mutect2, varscan2
- ATP2B4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58175265; called by muse, mutect2
- B4GAT1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759960341, COSV60820326; called by mutect2, varscan2
- BCKDHB | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV57514912; called by mutect2, varscan2
- BDP1 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as COSV62432311; called by muse, mutect2, varscan2
- BRINP1 | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs760601783, COSV56304243; called by mutect2, varscan2
- BRINP2 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV64178386; called by muse, varscan2
- BTAF1 | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV56435841; called by muse, mutect2, varscan2
- C16orf71 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs375626582; called by mutect2, varscan2
- C19orf33 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1218784912, COSV56650715; called by muse, mutect2, varscan2
- C1GALT1C1L | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 105/495 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.916); catalogued as COSV56754306; called by muse, mutect2, varscan2
- CA5A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs747262976, COSV59241572; called by mutect2, varscan2
- CABP4 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs966008036, COSV56885213; called by mutect2, varscan2
- CACNA1S | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs777920946, COSV62941033; ClinVar: uncertain significance; called by mutect2, varscan2
- CACNA2D3 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55552251; called by muse, mutect2, varscan2
- CAPN5 | c.383C>T p.S128L (on ENST00000456580; = p.S88L on NM_004055.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs782133997, COSV53689197; called by mutect2, varscan2
- CASP5 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829553; called by muse, mutect2, varscan2
- CBX8 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369528313; called by mutect2, varscan2
- CCDC141 | c.2647C>T p.R883C | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs186074315, COSV55376396; called by mutect2, varscan2
- CCDC144A | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV60699402; called by muse, mutect2, varscan2
- CCDC172 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60938410; called by muse, mutect2, varscan2
- CCER1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.917); catalogued as COSV62647410, COSV62649055; called by mutect2, varscan2
- CCR3 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656362, COSV62464152; called by muse, mutect2, varscan2
- CD1B | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1224540954, COSV63804205; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CD86 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52605405; called by muse, mutect2, varscan2
- CD96 | c.1720G>A p.E574K (on ENST00000283285 / NM_198196.3; = p.E558K on NM_005816.5) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201121432, COSV51912523, COSV51916031; called by mutect2, varscan2
- CDK18 | c.440G>A p.S147N (on ENST00000506784 / NM_212503.3; = p.S117N on NM_002596.4) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs867359696, COSV63727929; called by muse, mutect2, varscan2
- CDRT1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as rs368578151; called by muse, mutect2, varscan2
- CEACAM18 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV67283365; called by muse, mutect2, varscan2
- CEP85L | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62646205; called by muse, mutect2, varscan2
- CFAP300 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866788183, COSV71570844; called by muse, mutect2, varscan2
- CHD4 | c.4583C>T p.P1528L (on ENST00000357008 / NM_001363606.2; = p.P1541L on NM_001273.5) | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58899955; called by muse, mutect2, varscan2
- CHIT1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV55147741; called by muse, mutect2, varscan2
- CNKSR2 | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV54253613; called by mutect2, varscan2
- CNOT1 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55318543; called by muse, mutect2, varscan2
- CNPPD1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55408271; called by muse, mutect2, varscan2
- CNTD1 | c.723A>C p.Q241H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59312225; called by muse, mutect2, varscan2
- COL10A1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572843; called by mutect2, varscan2
- COL19A1 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767257431, COSV59577309; called by muse, mutect2, varscan2
- COL22A1 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57334530; called by muse, varscan2
- COL4A5 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV60360638; called by muse, mutect2, varscan2
- COL5A3 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV53413440; called by muse, mutect2, varscan2
- CPZ | c.1759G>A p.G587R (on ENST00000360986 / NM_001014447.3; = p.G576R on NM_003652.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as rs766618011, COSV59923889; called by muse, mutect2, varscan2
- CRB2 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV100749694, COSV63503990; called by muse, mutect2, varscan2
- CSMD1 | c.9211G>A p.E3071K (on ENST00000520002; = p.E3070K on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1357835057, COSV59341817; called by muse, mutect2
- CYP2C19 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1373273817, COSV64908271; called by muse, mutect2, varscan2
- DAPP1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56451992; called by muse, mutect2, varscan2
- DEFB115 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV68723225, COSV68723495; called by muse, mutect2, varscan2
- DEFB116 | c.132A>T p.Q44H | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV68722236; called by mutect2, varscan2
- DEFB119 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 124/230 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1411337088, COSV53620195; called by muse, mutect2, varscan2
- DHRS9 | c.311A>T p.K104I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV59140456; called by mutect2, varscan2
- DLK1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs770804393, COSV57992280; called by mutect2, varscan2
- DMC1 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53258994; called by muse, mutect2, varscan2
- DMP1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs866234685, COSV56820722; called by muse, mutect2, varscan2
- DMXL2 | c.2146C>T p.H716Y | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV51841111, COSV51849412; called by muse, mutect2, varscan2
- DNAH5 | c.13084G>A p.D4362N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV54234974; called by mutect2, varscan2
- DNAH8 | c.6091C>T p.L2031F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59458429; called by muse, mutect2, varscan2
- DOCK4 | c.5738C>T p.P1913L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV70239290; called by muse, mutect2, varscan2
- DRAM1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.515); catalogued as COSV51598752; called by mutect2, varscan2
- DSG3 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.232); catalogued as COSV57127420; called by muse, mutect2, varscan2
- DUOX2 | c.2773C>T p.H925Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs1368150062, COSV66532878; called by mutect2, varscan2
- E2F8 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs780620679, COSV51464495; called by mutect2, varscan2
- EHD4 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as rs1345286815, COSV55005563; called by mutect2, varscan2
- ELL2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550971003, COSV52983480; called by muse, mutect2, varscan2
- ELMOD1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.593); catalogued as COSV56193673; called by muse, mutect2, varscan2
- ELOA3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 27/400 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV55294493; called by muse, mutect2
- ENDOD1 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV53590003; called by muse, mutect2, varscan2
- ENG | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV61227882; called by muse, mutect2, varscan2
- ENGASE | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs200087247; called by muse, mutect2, varscan2
- ENOX1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54897413; called by muse, mutect2, varscan2
- EPB41L4B | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs758983596, COSV65803753; called by mutect2, varscan2
- EPHA6 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67571138, COSV67578619; called by muse, mutect2, varscan2
- ERCC3 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139049289; called by mutect2, varscan2
- EVC2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as rs1190178654, COSV60392919; called by muse, mutect2, varscan2
- EVI5L | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs368979408; called by mutect2, varscan2
- EXD1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59254835; called by muse, varscan2
- F8 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64272666, COSV64275078, COSV64276696; called by muse, mutect2, varscan2
- FAM234A | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51451618; called by muse, mutect2, varscan2
- FAM237A | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69305144; called by muse, mutect2, varscan2
- FARS2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51169869; called by muse, mutect2, varscan2
- FAT3 | c.10442C>T p.P3481L | Missense Mutation (SNP) | VAF 124/600 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53131945; called by muse, varscan2
- FGD4 | c.906T>A p.Y302* | Nonsense Mutation (SNP) | VAF 32/263 reads (12%) | catalogued as COSV56785926; called by muse, mutect2, varscan2
- GCFC2 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as COSV58080813; called by muse, mutect2, varscan2
- GCG | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64961676; called by muse, mutect2, varscan2
- GIMAP7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57959691; called by muse, mutect2, varscan2
- GJA5 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54784904; called by muse, mutect2, varscan2
- GLYAT | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as COSV53539738; called by muse, mutect2, varscan2
- GMDS | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66432390, COSV66437033; called by muse, mutect2, varscan2
- GML | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs762352406, COSV55277252; called by muse, mutect2, varscan2
- GPR137 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57402405, COSV57402757; called by muse, mutect2, varscan2
- GPR65 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1218693316, COSV50863147; called by muse, mutect2, varscan2
- GPRC5C | c.572G>A p.R191Q (on ENST00000652232; = p.R146Q on NM_018653.4) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs754753662, COSV100703047, COSV61237544; called by muse, mutect2, varscan2
- GRIK1 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV58722730; called by muse, mutect2, varscan2
- GRIN3A | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV62453005; called by muse, mutect2, varscan2
- GRM5 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59612133; called by muse, mutect2, varscan2
- GSTCD | c.1798C>T p.R600* (on ENST00000360505 / NM_001031720.3; = p.R513* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs375779179; called by mutect2, varscan2
- GUCY1A2 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs1202007346, COSV56487449; called by muse, mutect2, varscan2
- HCN4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1229232018, COSV56084789; called by mutect2, varscan2
- HHLA2 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1455892963, COSV63316566; called by mutect2, varscan2
- IGHE | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.071); catalogued as rs376841476; called by mutect2, varscan2
- IGHV3-13 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs781808181; called by muse, mutect2, varscan2
- IGKV1D-16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs746286068; called by muse, varscan2
- IGSF22 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60035679; called by muse, mutect2, varscan2
- IKBKE | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV65625961; called by muse, mutect2, varscan2
- IRAK2 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56528581; called by muse, mutect2, varscan2
- ITGAL | c.1721T>A p.V574E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63322921; called by muse, varscan2
- ITLN1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs147618489; called by muse, mutect2, varscan2
- JCAD | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV64760390; called by muse, mutect2
- KALRN | c.7663G>A p.G2555R (on ENST00000360013 / NM_001024660.4; = p.G858R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293710603, COSV52248729, COSV52259099; called by muse, varscan2
- KCNC2 | c.1472G>T p.R491M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV54367857, COSV54371961; called by mutect2, varscan2
- KCNC4 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV63925949; called by muse, varscan2
- KCNG4 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749008374, COSV57584562; called by mutect2, varscan2
- KCNJ9 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63631734; called by muse, mutect2, varscan2
- KCNN1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55839871; called by muse, varscan2
- KCNQ1 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV50114779; called by muse, mutect2, varscan2
- KCNQ5 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV59653883; called by mutect2, varscan2
- KIF6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as rs766052103, COSV54682995; called by muse, mutect2, varscan2
- KIR2DL4 | c.942G>A p.M314I (on ENST00000396284; = p.M240I on NM_001080770.2) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV58488477; called by mutect2, varscan2
- KLHDC7A | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs946220917, COSV68770192; called by muse, mutect2, varscan2
- KMT2A | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV63288010; called by muse, mutect2, varscan2
- KRT34 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1282301942, COSV67449751; called by muse, mutect2, varscan2
- KRT72 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV53374985; called by muse, mutect2, varscan2
- KRT85 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57737336; called by muse, mutect2, varscan2
- LILRA2 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs1470729988, COSV52188509; called by muse, mutect2, varscan2
- LILRB5 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | catalogued as rs1173524849, COSV60258788; called by muse, mutect2, varscan2
- LIPE | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs746653161, COSV99733936; called by muse, mutect2, varscan2
- LIPE | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99733938; called by muse, mutect2, varscan2
- LLGL1 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57498933; called by muse, mutect2, varscan2
- LRRC56 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54243228; called by muse, varscan2
- LRRC56 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as COSV99529740, COSV99530663; called by muse, mutect2, varscan2
- LRRK2 | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV54158691; called by muse, mutect2, varscan2
- MAGEB18 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as COSV57464389; called by mutect2, varscan2
- MAGEC1 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV53575742; called by muse, mutect2, varscan2
- MAGEE1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV100819334; called by muse, mutect2, varscan2
- MAMDC4 | c.3434A>C p.N1145T (on ENST00000445819; = p.N1066T on NM_206920.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV56376304; called by muse, varscan2
- MAP3K4 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62335170; called by muse, mutect2, varscan2
- MARCO | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV59055668; called by muse, mutect2, varscan2
- MBD5 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV68698065; called by muse, mutect2, varscan2
- MBD5 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV68698068; called by muse, mutect2, varscan2
- MBL2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV64758143; called by muse, mutect2, varscan2
- MECOM | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs865872961, COSV72110690; called by muse, mutect2, varscan2
- METTL17 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53870017; called by muse, mutect2, varscan2
- MOGAT2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243190255, COSV52220036; called by muse, mutect2, varscan2
- MORN5 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751585952, COSV65648473; called by mutect2, varscan2
- MSR1 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50506797, COSV50516546; called by muse, mutect2, varscan2
- MUC16 | c.25474G>A p.E8492K | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.205); catalogued as COSV67444218; called by muse, varscan2
- MUC16 | c.10751C>T p.S3584F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV67468124; called by muse, mutect2, varscan2
- MUC16 | c.7292C>T p.S2431F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67475905; called by muse, mutect2, varscan2
- MUC5B | c.11098G>A p.A3700T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs761966007, COSV71589918; called by muse, mutect2, varscan2
- MYH1 | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs139013228, COSV56849765; called by mutect2, varscan2
- MYH3 | c.5789C>T p.S1930F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV56866687; called by muse, mutect2, varscan2
- MYH7B | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV52679424; called by muse, mutect2, varscan2
- MYH8 | c.2879T>C p.L960P | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67967623; called by muse, mutect2, varscan2
- MYO15A | c.6577G>A p.G2193S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV52759566; called by muse, mutect2, varscan2
- MYO3A | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56319572; called by muse, mutect2, varscan2
- MYO9A | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 67/98 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1459152181, COSV61850265; called by mutect2, varscan2
- MYOCD | c.1599G>A p.W533* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV58499691; called by muse, mutect2, varscan2
- MYOF | c.4393G>A p.E1465K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV63706302; called by mutect2, varscan2
- NAA16 | c.1233C>A p.F411L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV65064258; called by mutect2, varscan2
- NELL1 | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54282468; called by mutect2, varscan2
- NIBAN1 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs754387667, COSV62284476; called by muse, mutect2, varscan2
- NLRC3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV57092570; called by muse, mutect2, varscan2
- NLRP10 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60780899; called by muse, mutect2, varscan2
- NLRP12 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145015, COSV60750022; called by mutect2, varscan2
- NMBR | c.48T>A p.N16K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99237151; called by mutect2, varscan2
- NMBR | c.47A>C p.N16T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99237153; called by muse, mutect2, varscan2
- NOS1AP | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV62634327; called by muse, mutect2, varscan2
- NRG1 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs555525050, COSV55157135; called by muse, mutect2, varscan2
- NRK | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV54599821; called by muse, mutect2, varscan2
- NTRK1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1323232384, COSV62325247; called by muse, mutect2, varscan2
- NUSAP1 | c.384A>T p.R128S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.228); catalogued as COSV52971791; called by muse, mutect2, varscan2
- NVL | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.24); catalogued as COSV55874604, COSV99893869; called by muse, mutect2, varscan2
- OPN5 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs201533729, COSV55244422; called by muse, mutect2, varscan2
- OR10H5 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58278489; called by mutect2, varscan2
- OR14K1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99315039, COSV99315108; called by muse, mutect2, varscan2
- OR1A1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs750409672, COSV58404104; called by muse, mutect2, varscan2
- OR4N5 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs1265321824, COSV61320307; called by muse, mutect2, varscan2
- OR5H15 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV62948448; called by muse, mutect2, varscan2
- OR7D4 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV58071961; called by muse, mutect2, varscan2
- OR9Q1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.3); catalogued as COSV59042359; called by muse, mutect2, varscan2
- OXR1 | c.2090C>T p.A697V (on ENST00000442977 / NM_001198532.1; = p.A669V on NM_018002.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs1358319268, COSV52425183; called by mutect2, varscan2
- PAM | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371136481; called by mutect2, varscan2
- PAPOLB | c.1643T>A p.L548* | Nonsense Mutation (SNP) | VAF 66/158 reads (42%) | catalogued as COSV68201878; called by muse, mutect2, varscan2
- PCARE | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV59055657; called by muse, mutect2, varscan2
- PCDH15 | c.4757G>A p.R1586K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as COSV57338118; called by muse, mutect2, varscan2
- PCDHB2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV50564015; called by muse, mutect2, varscan2
- PCGF6 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1475156309, COSV61495439; called by mutect2, varscan2
- PCLO | c.8666C>T p.S2889F | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV61644724; called by muse, mutect2, varscan2
- PDE4D | c.970C>T p.R324W (on ENST00000340635 / NM_001104631.2; = p.R188W on NM_006203.4) | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV57718441; called by mutect2, varscan2
- PHKA2 | c.918+2T>C p.X306_splice | Splice Site (SNP) | VAF 83/119 reads (70%) | catalogued as COSV66053658; called by muse, mutect2, varscan2
- PIGO | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV53053307; called by muse, mutect2, varscan2
- PIGU | c.1132T>C p.Y378H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54163986; called by muse, mutect2, varscan2
- PLA2R1 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV51781265; called by muse, mutect2, varscan2
- PLCB4 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV53806549; called by mutect2, varscan2
- PLCG2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63871661; called by muse, mutect2, varscan2
- PLEC | c.6703G>T p.V2235L (on ENST00000322810 / NM_201380.4; = p.V2125L on NM_000445.5) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV59653400; called by muse, mutect2, varscan2
- PM20D1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs964719324, COSV65649157; called by mutect2, varscan2
- PMFBP1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.698); catalogued as COSV52826506, COSV99031322; called by muse, mutect2, varscan2
- POLL | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV54576052; called by muse, mutect2, varscan2
- PPFIA2 | c.2285G>A p.G762D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV61038992; called by muse, mutect2, varscan2
- PPP1R3A | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52875161, COSV52885570; called by muse, mutect2, varscan2
- PRKCG | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs1442155032, COSV54724494; called by muse, varscan2
- PRKG1 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64773052; called by muse, varscan2
- PRLR | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51495402, COSV51497856; called by mutect2, varscan2
- PSEN1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56195256; called by muse, mutect2, varscan2
- PSG5 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1247547564, COSV61654523; called by muse, mutect2, varscan2
- RIMS2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.901); catalogued as COSV68113195; called by muse, mutect2, varscan2
- RIMS2 | c.4531G>A p.E1511K (on ENST00000666250 / NM_001348490.2; = p.E1082K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs549202122, COSV51651550; called by muse, mutect2, varscan2
- RIN2 | c.1225C>T p.R409W (on ENST00000255006 / NM_001242581.1; = p.R360W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54790082; called by muse, mutect2, varscan2
- RIPK3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as rs753342911, COSV53476076; called by muse, mutect2, varscan2
- ROS1 | c.4736G>A p.R1579K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV63856953; called by muse, varscan2
- RTL10 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs763737723, COSV60735933; called by mutect2, varscan2
- RUFY4 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV60248178; called by mutect2, varscan2
- RXFP2 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as rs760591206, COSV53637245; called by muse, mutect2, varscan2
- SAMD9L | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59079427; called by muse, mutect2, varscan2
- SAXO1 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1273740080, COSV65868282, COSV65870694; called by muse, mutect2, varscan2
- SCN10A | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs767498321, COSV71861935, COSV71862668; called by mutect2, varscan2
- SCN11A | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1402458245, COSV56568195; called by muse, mutect2, varscan2
- SCN9A | c.3397C>A p.P1133T (on ENST00000303354; = p.P1122T on NM_002977.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs761748478, COSV100311967; called by mutect2, varscan2
- SCNN1G | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55599757; called by muse, mutect2, varscan2
- SDK1 | c.3437T>A p.F1146Y | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67375949; called by mutect2, varscan2
- SEMA6C | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59004707; called by mutect2, varscan2
- SERPINA1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63345593; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by muse, varscan2
- SEZ6L | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50662619; called by muse, mutect2, varscan2
- SFTPB | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60893605; called by muse, mutect2, varscan2
- SFXN4 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100341013; called by mutect2, varscan2
- SH3TC1 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1177119567, COSV55286088; called by mutect2, varscan2
- SHANK3 | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53187918; called by muse, mutect2, varscan2
- SI | c.3905G>A p.G1302E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014545; called by mutect2, varscan2
- SI | c.3904G>A p.G1302R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014548, COSV52284296; called by muse, mutect2, varscan2
- SIGLEC11 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV70222046; called by muse, mutect2, varscan2
- SIM1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV53493673; called by muse, mutect2
- SIRPB2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV63124297; called by muse, mutect2, varscan2
- SLC15A2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs751141184, COSV55197528; called by muse, mutect2, varscan2
- SLC24A3 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs755342135, COSV60123394; called by muse, varscan2
- SLC25A46 | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100582542; called by muse, mutect2, varscan2
- SLC26A9 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100536151; called by muse, mutect2, varscan2
- SLC26A9 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100536155; called by muse, mutect2, varscan2
- SLC2A14 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs766115391, COSV61586459; called by mutect2, varscan2
- SLC35G2 | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as COSV67588561; called by muse, mutect2, varscan2
- SLIT3 | c.3169G>A p.G1057R | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV60616926; called by muse, mutect2, varscan2
- SOAT1 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV62655076; called by muse, mutect2, varscan2
- SOCS2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61392116; called by mutect2, varscan2
- SORL1 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV52756921; called by muse, mutect2, varscan2
- ST8SIA3 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 33/55 reads (60%) | PolyPhen probably damaging (0.977); catalogued as rs267605214, COSV60654522; called by muse, mutect2, varscan2
- STAB1 | c.6617G>A p.R2206Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs148752341; called by muse, mutect2, varscan2
- STARD13 | c.1976C>T p.A659V (on ENST00000336934 / NM_001243476.3; = p.A541V on NM_052851.3) | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV55230210; called by muse, mutect2, varscan2
- STON1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.379); catalogued as rs771061027, COSV59132694; called by muse, mutect2, varscan2
- SVOPL | c.616C>T p.R206C (on ENST00000419765; = p.R54C on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs143755972; called by muse, mutect2, varscan2
- SYNE1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs560155321, COSV54928364; ClinVar: uncertain significance; called by mutect2, varscan2
- SYNJ2 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV62898421; called by muse, mutect2, varscan2
- TACC2 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1354777334, COSV57760671; called by mutect2, varscan2
- TEKT1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV58623693; called by muse, mutect2, varscan2
- TGM4 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1019608729, COSV56094711; called by muse, varscan2
- THAP5 | c.691C>T p.H231Y (on ENST00000415914 / NM_001130475.3; = p.H189Y on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV50812337; called by muse, mutect2, varscan2
- TIMMDC1 | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV51787132; called by muse, mutect2, varscan2
- TMEM130 | c.1249C>T p.R417C (on ENST00000416379 / NM_001134450.2; = p.R405C on NM_152913.3) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782136245, COSV59559438; called by mutect2, varscan2
- TMEM266 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs773264443, COSV66380007; called by mutect2, varscan2
- TRAF1 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65868769; called by mutect2, varscan2
- TRIML2 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV58717467, COSV58720307; called by muse, mutect2, varscan2
- TRIP12 | c.4280C>T p.S1427F | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52266838, COSV52272983; called by muse, mutect2, varscan2
- TRPV6 | c.2205G>A p.W735* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as rs1290415577, COSV63892308; called by muse, mutect2, varscan2
- TSHZ2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.566); catalogued as rs200752097, COSV61589598; called by muse, mutect2, varscan2
- TTC37 | c.3053C>T p.T1018I | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100706460; called by muse, mutect2, varscan2
- TTC37 | c.3052A>T p.T1018S | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100706461; called by muse, mutect2, varscan2
- UGT2B7 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as COSV59444091; called by mutect2, varscan2
- UGT3A1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs1357338499, COSV99072894, COSV99954473; called by muse, varscan2
- UGT3A2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as rs147315371, COSV56928456; called by muse, mutect2, varscan2
- ULBP3 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.066); catalogued as rs779800228, COSV66254168; called by muse, mutect2, varscan2
- UNC13D | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.155); catalogued as COSV52885575; called by muse, mutect2, varscan2
- UNC5C | c.1718G>A p.R573K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1219708513, COSV101497961, COSV71660723; called by muse, mutect2, varscan2
- VAT1L | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs770790699, COSV56822405; called by mutect2, varscan2
- VHL | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.199); catalogued as CM941376, CM941377, COSV56542337, COSV56553831, COSV56565181; called by muse, mutect2, varscan2
- VPS54 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV55442178; called by muse, mutect2, varscan2
- VWF | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV54618614; called by muse, mutect2, varscan2
- WNK3 | c.4178C>T p.S1393L | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs781830908, COSV63611806, COSV63615042; called by muse, mutect2, varscan2
- WWC1 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV99514548; called by muse, mutect2, varscan2
- XRN2 | c.2528G>C p.G843A | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.068); catalogued as COSV65870297; called by muse, mutect2, varscan2
- YME1L1 | c.866C>T p.S289F (on ENST00000326799 / NM_139312.3; = p.S232F on NM_014263.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58760071; called by muse, mutect2, varscan2
- ZDBF2 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV65627449; called by muse, mutect2, varscan2
- ZEB1 | c.1771A>T p.N591Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58042935; called by mutect2, varscan2
- ZFYVE28 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99342598; called by muse, mutect2, varscan2
- ZMIZ2 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54809155; called by muse, mutect2, varscan2
- ZMYND8 | c.244C>T p.P82S (on ENST00000311275 / NM_001363741.2; = p.P102S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53691047; called by muse, mutect2, varscan2
- ZNF337 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV53321975; called by muse, mutect2, varscan2
- ZNF385B | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV61178951; called by muse, mutect2, varscan2
- ZNF394 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV61793811; called by muse, mutect2, varscan2
- ZNF417 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1263886805, COSV56308754; called by mutect2, varscan2
- ZNF428 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV56194028; called by mutect2, varscan2
- ZNF831 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV64038544; called by muse, mutect2, varscan2
- ZNF835 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV73379380; called by mutect2, varscan2
- ZSWIM2 | c.1180A>C p.T394P | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV54576651; called by muse, mutect2, varscan2
- ACACA | c.1166C>G p.A389G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CYP19A1 | c.1354_1361del p.V452Sfs*15 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.3653G>A p.G1218E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HEY1 | c.411_412insAAC p.Y137_L138insN | In Frame Ins (INS) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- TNS2 | c.602del p.H201Lfs*97 (on ENST00000314250 / NM_170754.4; = p.H211Lfs*97 on NM_015319.2) | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- ABAT | c.9C>T p.S3= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs867072039, COSV51624808; called by muse, mutect2, varscan2
- ABCA2 | c.7164C>T p.F2388= (on ENST00000614293; = p.F2358= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs369175136, COSV55803085, COSV55808308; called by mutect2, varscan2
- ABCC8 | c.1737C>T p.S579= | Silent (SNP) | VAF 105/516 reads (20%) | catalogued as rs970527431, COSV56852755; called by muse, mutect2, varscan2
- ACSM2B | c.205C>T p.L69= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61658566; called by muse, mutect2, varscan2
- ACTL9 | c.1128G>A p.R376= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1354488069, COSV61005593; called by muse, mutect2, varscan2
- ADAMTS9 | c.4725C>T p.S1575= | Silent (SNP) | VAF 73/248 reads (29%) | catalogued as COSV55784224; called by muse, mutect2, varscan2
- ADGRG6 | c.3333C>T p.F1111= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51595039; called by mutect2, varscan2
- ADGRG7 | c.591A>C p.S197= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56298217; called by mutect2, varscan2
- ANKS1B | c.2133G>A p.E711= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61359065; called by muse, mutect2, varscan2
- ARFGEF2 | c.261C>T p.S87= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV64213236; called by muse, mutect2, varscan2
- ARHGAP5 | c.2463C>T p.I821= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV61536431; called by mutect2, varscan2
- ARHGEF18 | c.1329C>T p.L443= (on ENST00000359920 / NM_001130955.2; = p.L339= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs746987704, COSV60471094; called by mutect2, varscan2
- ARID5B | c.2112C>T p.L704= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV54423352; called by muse, mutect2, varscan2
- ATP10A | c.426C>T p.H142= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs779585158, COSV63519431; called by muse, mutect2, varscan2
- ATP10B | c.2700G>A p.T900= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as rs370090714; called by muse, mutect2, varscan2
- BANK1 | c.642C>T p.F214= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV59845355; called by mutect2, varscan2
- BCDIN3D | c.486C>T p.F162= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BPI | c.1107C>T p.A369= (on ENST00000262865; = p.A365= on NM_001725.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs144501421; called by muse, mutect2, varscan2
- CABP1 | c.801C>T p.I267= (on ENST00000316803 / NM_001033677.1; = p.I64= on NM_004276.5) | Silent (SNP) | VAF 107/256 reads (42%) | catalogued as rs1462627269, COSV56459204; called by muse, mutect2, varscan2
- CAMK2G | c.486C>T p.I162= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV59483096; called by mutect2, varscan2
- CATSPERB | c.1785G>A p.T595= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs757435600, COSV56428899; called by muse, mutect2, varscan2
- CBLC | c.633C>T p.F211= | Silent (SNP) | VAF 70/332 reads (21%) | catalogued as rs777975775, COSV54321121; called by muse, mutect2, varscan2
- CBX8 | c.609C>T p.P203= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99485803; called by muse, mutect2, varscan2
- CCN4 | c.948G>A p.K316= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV51533035; called by muse, mutect2, varscan2
- CD163L1 | c.831G>A p.L277= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as COSV58018853; called by muse, mutect2, varscan2
- CD5L | c.108G>A p.R36= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1192877651, COSV63822370; called by muse, mutect2, varscan2
- CDH23 | c.2031C>T p.F677= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs759239589, COSV54925526; called by mutect2, varscan2
- CFAP54 | c.6814C>T p.L2272= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs778942905, COSV61572951; called by muse, mutect2, varscan2
- CHFR | c.279G>A p.Q93= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV57175618; called by muse, mutect2, varscan2
- CHST12 | c.777C>T p.F259= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs147486579, COSV51676220; called by muse, mutect2, varscan2
- CILP | c.1758C>T p.I586= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV56025470; called by mutect2, varscan2
- CMTR1 | c.681C>T p.I227= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as COSV65090745; called by muse, mutect2, varscan2
- COL21A1 | c.582G>A p.V194= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55168684; called by muse, mutect2, varscan2
- CPN2 | c.537C>T p.N179= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1241375599, COSV60469797; called by muse, mutect2, varscan2
- CPNE5 | c.459C>T p.S153= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV55197721; called by muse, mutect2, varscan2
- CREB5 | c.300G>A p.S100= (on ENST00000357727 / NM_182898.4; = p.S93= on NM_004904.3) | Silent (SNP) | VAF 147/407 reads (36%) | catalogued as rs756899888, COSV63223386; called by muse, mutect2, varscan2
- CRISPLD2 | c.861C>T p.V287= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs756555506, COSV52277013, COSV52280521; called by mutect2, varscan2
- CSF2RA | c.321G>A p.Q107= | Silent (SNP) | VAF 100/199 reads (50%) | catalogued as COSV62625252, COSV62625753; called by muse, mutect2, varscan2
- CSMD2 | c.5670C>T p.I1890= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as COSV53904435; called by muse, mutect2, varscan2
- DCC | c.3435G>A p.Q1145= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as COSV71434155; called by muse, mutect2, varscan2
- DEF8 | c.582C>T p.I194= (on ENST00000268676 / NM_207514.3; = p.I133= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV51919826, COSV99240342; called by muse, mutect2, varscan2
- DHX30 | c.444C>T p.S148= (on ENST00000445061 / NM_138615.3; = p.S109= on NM_014966.3) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV62395479; called by muse, mutect2, varscan2
- DIP2C | c.2580C>T p.S860= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55164499; called by muse, mutect2
- DMBT1 | c.6975C>T p.F2325= (on ENST00000338354 / NM_001377530.1; = p.F1568= on NM_004406.3) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57547324; called by muse, mutect2, varscan2
- DNAH5 | c.6666G>A p.L2222= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV54234981; called by muse, mutect2, varscan2
- DNAJC22 | c.27T>C p.Y9= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV67711922, COSV67712352; called by muse, mutect2, varscan2
- DPEP2 | c.1284C>T p.S428= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs746028978, COSV52055035; called by muse, mutect2, varscan2
- EPHB6 | c.1977C>T p.I659= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV63892302; called by muse, mutect2, varscan2
- ERMAP | c.210C>T p.F70= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV60274772; called by muse, mutect2, varscan2
- ESYT3 | c.768C>T p.T256= | Silent (SNP) | VAF 46/210 reads (22%) | catalogued as COSV56680854; called by muse, mutect2, varscan2
- EXT1 | c.1452C>T p.I484= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV65481486; called by muse, mutect2, varscan2
- FAM104A | c.168G>A p.A56= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52147347; called by muse, mutect2, varscan2
- FAM193A | c.3054C>T p.L1018= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs752340131, COSV61195833; called by muse, mutect2, varscan2
- FAT4 | c.6210C>T p.F2070= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs771989829, COSV58692815; ClinVar: likely benign; called by mutect2, varscan2
- FCGBP | c.801C>T p.F267= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs557474677; called by muse, mutect2, varscan2
- FHL3 | c.39C>T p.S13= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1290318175, COSV65952643; called by muse, mutect2, varscan2
- FILIP1 | c.2028C>T p.F676= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV52730205; called by muse, mutect2, varscan2
- FLRT3 | c.1524C>T p.N508= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV54006019; called by muse, mutect2, varscan2
- FOCAD | c.5016C>T p.F1672= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as COSV58102212; called by muse, mutect2, varscan2
- FSTL4 | c.2148C>T p.I716= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV54775685; called by muse, mutect2, varscan2
- FYB1 | c.6G>A p.A2= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs774770343, COSV60942303; called by muse, mutect2, varscan2
- FZR1 | c.591C>A p.S197= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV58052280; called by mutect2, varscan2
- GHRHR | c.519C>T p.I173= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV58197085; called by muse, mutect2, varscan2
- GLB1 | c.1128G>A p.K376= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56565305; called by muse, mutect2
- GPR158 | c.1035C>T p.F345= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs767413538, COSV100894148, COSV66270021; called by mutect2, varscan2
- GPR78 | c.171G>A p.A57= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1553873744, COSV66763360; called by mutect2, varscan2
- GRIK3 | c.2643G>A p.Q881= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV66141926; called by muse, mutect2, varscan2
- GRIN3A | c.2967G>A p.E989= | Silent (SNP) | VAF 68/102 reads (67%) | catalogued as COSV62455503; called by muse, mutect2, varscan2
- GRM3 | c.130C>T p.L44= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as rs369915149; called by muse, mutect2, varscan2
- GRM3 | c.723C>T p.I241= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs923538983, COSV64469476; called by muse, mutect2, varscan2
- GYS1 | c.1779C>T p.S593= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs372542706; called by mutect2, varscan2
- HIVEP3 | c.1141C>T p.L381= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV56017886, COSV56024917; called by muse, mutect2, varscan2
- HSD17B12 | c.300G>A p.V100= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1258596632, COSV53501022; called by muse, mutect2, varscan2
- IGHJ2 | c.12C>T p.F4= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs782598282; called by muse, mutect2, varscan2
- IRX1 | c.405C>T p.T135= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV57360430; called by muse, mutect2, varscan2
- IVD | c.786G>A p.K262= (on ENST00000651168; = p.K259= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV51099745; called by muse, mutect2, varscan2
- JPH3 | c.423C>T p.G141= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs774801127, COSV52469583; called by muse, mutect2, varscan2
- KCNH2 | c.2184C>A p.I728= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV51198115; called by muse, varscan2
- KCNJ12 | c.963C>T p.I321= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59163030; called by mutect2, varscan2
- KCNT1 | c.2964C>T p.L988= (on ENST00000488444; = p.L1007= on NM_020822.3) | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV53704244; called by muse, mutect2, varscan2
- KCNV1 | c.597C>T p.I199= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs267601724, COSV52085279; called by muse, mutect2, varscan2
- KRT24 | c.732G>A p.V244= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV52880731; called by muse, mutect2, varscan2
- LIFR | c.2904G>A p.G968= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV54692907; called by muse, mutect2, varscan2
- LIN28B | c.684G>A p.T228= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1489028495, COSV61494461; called by mutect2, varscan2
- LRP4 | c.2829C>T p.S943= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV66136700; called by muse, mutect2, varscan2
- LYVE1 | c.156G>A p.L52= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV56282988; called by mutect2, varscan2
- MGMT | c.321C>T p.I107= (on ENST00000306010; = p.I76= on NM_002412.5) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs112373357; called by mutect2, varscan2
- MINDY4 | c.1399C>T p.L467= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV54675402; called by muse, mutect2, varscan2
- MOB3A | c.600C>T p.I200= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs754681414, COSV63865945; called by mutect2, varscan2
- MROH2B | c.2535G>A p.L845= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV68184481; called by mutect2, varscan2
- MUC16 | c.41325G>A p.K13775= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV66693800; called by muse, mutect2, varscan2
- MUC16 | c.27093G>A p.T9031= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs562688434, COSV67475899, COSV67493620; called by muse, mutect2, varscan2
- MYH1 | c.2418G>A p.Q806= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs752321678, COSV56851444; called by muse, mutect2, varscan2
- NCKAP1L | c.2190G>A p.T730= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs199847924, COSV53205271; called by mutect2, varscan2
- NDST4 | c.1467A>C p.P489= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1245571496, COSV52125456; called by muse, mutect2, varscan2
- NISCH | c.3732C>T p.F1244= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV58738973; called by muse, mutect2, varscan2
- NLRP1 | c.2676G>A p.P892= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs775814076, COSV52569635; called by mutect2, varscan2
- OBSCN | c.20862C>T p.T6954= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV62615881; called by muse, mutect2, varscan2
- OR2M7 | c.558C>T p.I186= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as COSV58739505; called by muse, mutect2, varscan2
- OR2T10 | c.426C>T p.L142= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1347272129, COSV57896191, COSV57896291, COSV57896464; called by muse, mutect2, varscan2
- OR2T33 | c.897G>A p.L299= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as COSV58815980; called by muse, mutect2, varscan2
- OR4B1 | c.744T>C p.F248= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV58883191; called by muse, mutect2, varscan2
- OR5M10 | c.219T>C p.Y73= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV73242356; called by muse, mutect2, varscan2
- PANK4 | c.1557C>T p.F519= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as COSV65867108; called by muse, mutect2, varscan2
- PDE2A | c.2058C>T p.I686= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as COSV57809258; called by muse, mutect2, varscan2
- PHC2 | c.1815C>T p.F605= (on ENST00000257118 / NM_198040.2; = p.F70= on NM_004427.4) | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV57105506; called by muse, mutect2, varscan2
- PI16 | c.945C>T p.I315= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV65320899; called by muse, mutect2, varscan2
- PIPOX | c.1081C>T p.L361= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV60142421; called by muse, mutect2, varscan2
- PIWIL4 | c.666T>C p.I222= | Silent (SNP) | VAF 34/183 reads (19%) | catalogued as COSV54410234; called by muse, mutect2, varscan2
- PKD1 | c.10041C>T p.S3347= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV51919298; called by muse, mutect2, varscan2
- PKHD1L1 | c.5553C>T p.I1851= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101006913, COSV65746186; called by mutect2, varscan2
- PKHD1L1 | c.9642C>T p.I3214= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs781642452, COSV101005270, COSV101006883, COSV65739814; called by muse, mutect2, varscan2
- PLEKHG4B | c.738C>T p.I246= (on ENST00000283426; = p.I602= on NM_052909.5) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs778596821, COSV52047962, COSV52049774; called by mutect2, varscan2
- PNLIP | c.111G>A p.T37= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs200222049, COSV65040959, COSV65041697; called by muse, mutect2, varscan2
- PNMA2 | c.328C>T p.L110= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV72908555; called by muse, mutect2, varscan2
- PPARA | c.375C>T p.F125= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV53079620; called by muse, mutect2, varscan2
- PPL | c.2427G>A p.R809= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100630605; called by muse, varscan2
- PRAMEF15 | c.603G>A p.L201= | Silent (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- PRDM16 | c.870C>T p.F290= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV54596396; called by muse, mutect2, varscan2
- PRKCQ | c.852C>T p.N284= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs758032733, COSV54113623; called by muse, mutect2, varscan2
- PSG9 | c.1110G>A p.G370= | Silent (SNP) | VAF 97/245 reads (40%) | catalogued as COSV52483534; called by muse, mutect2, varscan2
- RAB30 | c.606C>T p.F202= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52627369; called by mutect2, varscan2
- RBM41 | c.987C>T p.F329= | Silent (SNP) | VAF 76/117 reads (65%) | catalogued as rs200029592, COSV52564078; called by muse, varscan2
- RIN1 | c.348C>T p.F116= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs760724156, COSV60927470; called by mutect2, varscan2
- RIN2 | c.1224C>T p.P408= (on ENST00000255006 / NM_001242581.1; = p.P359= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99656762, COSV99657974; called by muse, mutect2, varscan2
- SCCPDH | c.114C>T p.S38= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV63618816; called by muse, mutect2, varscan2
- SCN10A | c.3870C>T p.I1290= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV71861933; called by muse, mutect2, varscan2
- SCN9A | c.3396C>T p.N1132= (on ENST00000303354; = p.N1121= on NM_002977.3) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100311968; called by mutect2, varscan2
- SDE2 | c.255C>T p.L85= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs748233042, COSV55251743; called by muse, mutect2, varscan2
- SDK2 | c.5796C>T p.F1932= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs953174501, COSV66189478; called by muse, mutect2, varscan2
- SEZ6L | c.468C>T p.L156= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV50668893, COSV50676161; called by muse, mutect2, varscan2
- SFTPD | c.912C>T p.V304= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs777015271, COSV64852996; called by mutect2, varscan2
- SHANK2 | c.4491G>A p.R1497= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV53604980; called by muse, mutect2, varscan2
- SIGLEC12 | c.918G>A p.T306= (on ENST00000291707 / NM_053003.4; = p.T188= on NM_033329.2) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs375071831; called by mutect2, varscan2
- SLC17A1 | c.1303C>T p.L435= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV55079907; called by muse, mutect2, varscan2
- SLC17A5 | c.444C>T p.V148= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV63287757; called by muse, mutect2, varscan2
- SLC22A9 | c.858C>T p.L286= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV54168070; called by muse, mutect2, varscan2
- SLC32A1 | c.927C>T p.S309= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV54147275; called by muse, mutect2, varscan2
- SLC36A2 | c.990C>T p.S330= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV58863860; called by muse, mutect2, varscan2
- SLC52A3 | c.1155C>T p.P385= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV54077978; called by muse, mutect2, varscan2
- SLC6A1 | c.1767G>A p.A589= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs748298652, COSV55119511; called by muse, mutect2, varscan2
- SLC6A17 | c.1878C>T p.V626= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs367697353; called by mutect2, varscan2
- SLC8A3 | c.1893C>T p.L631= (on ENST00000381269 / NM_183002.3; = p.L632= on NM_033262.4) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53690668; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2037C>T p.S679= (on ENST00000540229 / NM_001371097.1; = p.S618= on NM_001009562.4) | Silent (SNP) | VAF 134/259 reads (52%) | catalogued as COSV101043265, COSV67445864; called by muse, mutect2, varscan2
- SLCO2B1 | c.579C>T p.F193= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs553595767, COSV56936401; called by muse, mutect2, varscan2
- SPATA31E1 | c.570C>T p.S190= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV57792960; called by muse, mutect2, varscan2
- SPATA45 | c.105G>A p.V35= | Silent (SNP) | VAF 32/196 reads (16%) | catalogued as COSV60572183; called by muse, mutect2, varscan2
- SUSD4 | c.1128C>T p.L376= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1368281198, COSV59554113; called by muse, mutect2, varscan2
- TBC1D4 | c.3700C>T p.L1234= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV66489942; called by muse, mutect2, varscan2
- TEKT1 | c.561C>T p.I187= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV58622268, COSV58623702; called by muse, mutect2, varscan2
- TERT | c.1566G>A p.R522= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs770410182, COSV57222894; ClinVar: likely benign; called by muse, mutect2, varscan2
- TG | c.7986C>T p.F2662= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV55082202; called by mutect2, varscan2
- TLR4 | c.2319G>A p.K773= (on ENST00000355622 / NM_138554.5; = p.K733= on NM_003266.4) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1461118385, COSV62923642; called by muse, mutect2, varscan2
- TMEM132E | c.1854C>T p.I618= (on ENST00000321639; = p.I708= on NM_001304438.2) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs755975030, COSV58698283; called by muse, mutect2, varscan2
- TOP3A | c.2046C>T p.F682= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58178702; called by muse, mutect2, varscan2
- TPO | c.1990C>T p.L664= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV61093410, COSV61104583; called by muse, mutect2, varscan2
- TPTE | c.246G>A p.K82= (on ENST00000618007 / NM_199261.4; = p.K64= on NM_199259.4) | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- TRANK1 | c.2395C>T p.L799= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs1453488310, COSV57154601; called by muse, mutect2, varscan2
- TRAV8-4 | c.288G>A p.T96= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs267603931; called by mutect2, varscan2
- TTLL6 | c.2490C>T p.L830= (on ENST00000393382 / NM_001130918.3; = p.L523= on NM_173623.3) | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV64977813; called by muse, mutect2, varscan2
- UNC79 | c.2193G>A p.G731= (on ENST00000393151 / NM_001346218.2; = p.G554= on NM_020818.5) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV56381204; called by muse, mutect2, varscan2
- WNK3 | c.4497C>T p.H1499= | Silent (SNP) | VAF 84/114 reads (74%) | catalogued as rs1389550384, COSV63614771; called by muse, mutect2, varscan2
- WSCD2 | c.141G>A p.G47= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV54583074; called by muse, mutect2, varscan2
- WWC1 | c.1500C>T p.T500= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV99514551; called by mutect2, varscan2
- ZFP2 | c.522T>C p.T174= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs1368664439, COSV63726142; called by muse, mutect2, varscan2
- ZFPM2 | c.2778C>T p.S926= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs769197775, COSV101023045, COSV65874414; called by muse, mutect2, varscan2
- ZFYVE28 | c.885C>T p.P295= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99342595; called by mutect2, varscan2
- ZRANB3 | c.2232G>A p.R744= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs374358046; called by muse, mutect2, varscan2
- ZSWIM3 | c.1003C>T p.L335= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs1555828705, COSV54848094; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149848 C>T | 5'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- CFAP54 | c.8281+37G>A | Intron (SNP) | VAF 20/47 reads (43%) | called by mutect2, varscan2
- CLCA3P | n.586C>T | RNA (SNP) | VAF 12/19 reads (63%) | catalogued as rs545114481; called by mutect2, varscan2
- GRIA3 | c.2440-2712G>A | Intron (SNP) | VAF 34/53 reads (64%) | catalogued as COSV52067989; called by mutect2, varscan2
- KRT18P23 | chr22:44570567 G>A | 3'Flank (SNP) | VAF 6/12 reads (50%) | catalogued as rs368622443; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.583C>T | RNA (SNP) | VAF 25/107 reads (23%) | catalogued as rs782450421; called by muse, mutect2, varscan2
- NBL1 | chr1:19643390 G>A | 5'Flank (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99229378; called by muse, mutect2, varscan2
- NFASC | c.2470+2114G>A | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58364342; called by muse, mutect2, varscan2
- OBSCN | c.11659+4959C>T | Intron (SNP) | VAF 28/48 reads (58%) | catalogued as COSV99475107; called by muse, mutect2, varscan2
- TMC5 | c.1049-3520C>T | Intron (SNP) | VAF 26/52 reads (50%) | catalogued as rs902687135, COSV54901686, COSV99572269; called by muse, mutect2, varscan2
- TRIM5 | c.895+30C>T | Intron (SNP) | VAF 31/104 reads (30%) | catalogued as COSV100000159; called by muse, mutect2, varscan2
- WASF4P | n.508G>A | RNA (SNP) | VAF 17/26 reads (65%) | catalogued as rs1309100803; called by muse, mutect2, varscan2
